Somatic mutation profile of tumor specimen TCGA-IP-7968-01A (aliquot TCGA-IP-7968-01A-11D-2201-08) from TCGA case TCGA-IP-7968, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 74.2 years (27,114 days).
Specimen TCGA-IP-7968-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2a92e9e-cd4b-45f1-acdf-71551a693a49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IP-7968-10A (Blood Derived Normal), aliquot TCGA-IP-7968-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de52db3c-f78e-4825-969e-64fc28d09b74

The open-access MAF lists 117 somatic variants for this specimen: 90 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 24, Nonsense Mutation 10, Frame Shift Ins 3, Intron 2, Splice Site 1, Splice Region 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 24/31 reads (77%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.1331C>A p.A444D | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV53899268; called by muse, mutect2, varscan2
- AMOT | c.1685G>A p.R562H (on ENST00000371959 / NM_001113490.1; = p.R153H on NM_133265.3) | Missense Mutation (SNP) | VAF 88/137 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs139517376, COSV59061362; called by muse, mutect2, varscan2
- ARHGAP6 | c.1845C>G p.S615R | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV57292806; called by muse, mutect2, varscan2
- ASPM | c.7598C>G p.S2533C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV54126033, COSV54126089; called by muse, mutect2
- ASTN1 | c.3375G>T p.W1125C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV62492952, COSV62499991; called by muse, mutect2, varscan2
- BOD1L1 | c.2939C>T p.S980L | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV50007692; called by muse, mutect2, varscan2
- C1orf198 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.167); catalogued as COSV64174727; called by muse, mutect2, varscan2
- CD82 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758720179, COSV57034174; called by muse, mutect2, varscan2
- CDH11 | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51753799; called by muse, mutect2, varscan2
- COL11A1 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100618560, COSV62175504; called by muse, mutect2, varscan2
- CRB1 | c.3323C>T p.S1108F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66328994; called by muse, mutect2, varscan2
- DDX43 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV64836479; called by muse, mutect2, varscan2
- DIDO1 | c.3911C>T p.A1304V | Missense Mutation (SNP) | VAF 77/230 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as COSV56615729; called by muse, mutect2, varscan2
- DISP3 | c.847G>A p.G283S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53822232; called by muse, mutect2, varscan2
- DLGAP3 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.041); catalogued as rs146586197, COSV52392098, COSV99331996; called by muse, mutect2, varscan2
- DNAH17 | c.8891C>T p.A2964V | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760238543, COSV67756311; called by muse, mutect2, varscan2
- DPP6 | c.1334A>C p.K445T (on ENST00000377770 / NM_001364500.2; = p.K383T on NM_001936.5) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.386); catalogued as COSV59602140, COSV59626682; called by muse, mutect2, varscan2
- DPYSL4 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768468892, COSV58306285; called by muse, mutect2, varscan2
- DST | c.19214C>T p.P6405L (on ENST00000361203 / NM_001374722.1; = p.P4102L on NM_015548.5) | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs372733281; called by muse, mutect2, varscan2
- EPDR1 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV52258762, COSV52262160; called by muse, mutect2, varscan2
- FES | c.990G>A p.M330I | Missense Mutation (SNP) | VAF 717/802 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1328965624, COSV60997030; called by muse, varscan2
- FES | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 447/507 reads (88%) | catalogued as COSV60997040; called by muse, mutect2
- FPR3 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs746950422, COSV59328604; called by muse, mutect2, varscan2
- GALNT12 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs775453262, COSV66662252; called by muse, mutect2, varscan2
- GALNT3 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764878326, COSV67061451; called by muse, mutect2, varscan2
- GGTLC2 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV67853912; called by muse, mutect2, varscan2
- GPR174 | c.258T>A p.F86L | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV52131691; called by muse, varscan2
- GRIA4 | c.650G>C p.R217T | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as COSV56885507; called by muse, mutect2, varscan2
- HSPA12A | c.1478C>T p.A493V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs374696720; called by muse, mutect2, varscan2
- IL26 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs373868127; called by muse, mutect2, varscan2
- KCTD3 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1412591136, COSV52064808; called by muse, mutect2, varscan2
- KRT23 | c.1117C>T p.R373W | Missense Mutation (SNP) | VAF 47/576 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs575192650, COSV52927190, COSV52928635; called by muse, mutect2
- MAP3K15 | c.3464C>T p.A1155V | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs201603186, COSV58826934; called by muse, mutect2, varscan2
- METTL8 | c.224T>C p.L75P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV64549068; called by muse, mutect2
- MKRN3 | c.937A>T p.I313F | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58809019; called by muse, mutect2, varscan2
- MTA1 | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58755974; called by muse, mutect2, varscan2
- MTTP | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV55504383; called by muse, mutect2, varscan2
- MUC16 | c.28735T>A p.S9579T | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV67451428; called by muse, mutect2, varscan2
- NCOA5 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 71/202 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs41282786; called by muse, mutect2, varscan2
- NEUROD4 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as COSV54470812; called by muse, mutect2, varscan2
- NFATC2 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as COSV65353780; called by muse, mutect2, varscan2
- NIBAN2 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as COSV64823851; called by muse, mutect2, varscan2
- NTNG2 | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764547540, COSV62365118, COSV62367098; called by muse, mutect2, varscan2
- OR10X1 | c.596C>A p.A199E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV63767074, COSV63768020; called by muse, mutect2, varscan2
- OR2A2 | c.916A>T p.R306W | Missense Mutation (SNP) | VAF 71/101 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV68871008, COSV68871218; called by muse, mutect2, varscan2
- OR51B5 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV100332553; called by muse, mutect2, varscan2
- OR51B5 | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100332556; called by muse, mutect2, varscan2
- OR7D2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.202); catalogued as rs201184916, COSV60139140; called by muse, mutect2, varscan2
- OTOF | c.961-2A>C p.X321_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV55497896; called by muse, mutect2, varscan2
- PCDH10 | c.320A>G p.Q107R | Missense Mutation (SNP) | VAF 76/127 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1396018969, COSV52089107; called by muse, mutect2, varscan2
- PDE11A | c.1136C>A p.S379* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV53688826, COSV53706820; called by muse, mutect2, varscan2
- PLEKHG7 | c.1075A>G p.K359E | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV60821256; called by muse, mutect2
- PPIF | c.163A>T p.N55Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV56550949; called by muse, mutect2
- PRDM4 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 60/173 reads (35%) | catalogued as COSV57304859; called by muse, mutect2, varscan2
- PTPRM | c.3319G>A p.V1107I | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs751046402, COSV59843068; called by muse, mutect2, varscan2
- RAVER1 | c.820A>G p.M274V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0.05); catalogued as COSV53344277; called by muse, mutect2, varscan2
- RGS12 | c.2533C>T p.Q845* | Nonsense Mutation (SNP) | VAF 29/63 reads (46%) | catalogued as COSV58749497; called by muse, mutect2, varscan2
- RRP36 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 68/86 reads (79%) | catalogued as rs528827718, COSV55063685; called by muse, mutect2, varscan2
- RSF1 | c.1955G>A p.S652N | Missense Mutation (SNP) | VAF 95/138 reads (69%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV57837226; called by muse, mutect2, varscan2
- SALL4 | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as rs747787961, COSV53850364; called by muse, mutect2, varscan2
- SCN9A | c.2815G>A p.A939T (on ENST00000303354; = p.A928T on NM_002977.3) | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1064793264, COSV57602945; ClinVar: uncertain significance; called by muse, mutect2
- SEMA3B | c.2230C>T p.R744C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57112871; called by muse, mutect2, varscan2
- SGMS2 | c.68C>G p.T23S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV62988956; called by muse, mutect2, varscan2
- SKOR1 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58244255; called by muse, mutect2, varscan2
- SLC23A3 | c.798G>A p.S266= (on ENST00000409878 / NM_001144889.2; = p.R256Q on NM_144712.5) | Splice Region (SNP) | VAF 14/47 reads (30%) | catalogued as rs560144655, COSV55405875; called by muse, mutect2, varscan2
- SOX5 | c.950A>T p.Q317L | Missense Mutation (SNP) | VAF 60/119 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58621639; called by muse, mutect2, varscan2
- SPATA4 | c.490T>A p.F164I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV54589085, COSV54590495; called by muse, mutect2, varscan2
- TAOK2 | c.951C>A p.F317L | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV54233741; called by muse, mutect2, varscan2
- TRPC4 | c.109T>G p.L37V | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777267356, COSV58993066; called by muse, mutect2
- TSN | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 69/189 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV67605138; called by muse, mutect2, varscan2
- TTLL11 | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as rs754366015, COSV58643494, COSV58652982; called by muse, mutect2, varscan2
- TTN | c.31809A>C p.K10603N (on ENST00000591111; = p.K9676N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | PolyPhen benign (0.31); catalogued as COSV59925588; called by muse, mutect2, varscan2
- TUBA1A | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.069); catalogued as COSV55496979; called by muse, mutect2, varscan2
- WDR59 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 63/136 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.598); catalogued as rs1339818883, COSV50933085; called by muse, mutect2, varscan2
- WDR72 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs748071632, COSV64742553; called by muse, mutect2, varscan2
- ZFP36L2 | c.503G>A p.C168Y | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV56697238; called by muse, mutect2, varscan2
- ZNF471 | c.1012A>T p.R338* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as rs768391253, COSV57290242; called by muse, mutect2, varscan2
- ZNF512B | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 117/690 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.092); catalogued as rs570559377, COSV53866781; called by muse, mutect2, varscan2
- ZNF606 | c.2096G>A p.R699Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.117); catalogued as rs754720133, COSV58705294; called by muse, mutect2, varscan2
- ZNF655 | c.984G>T p.M328I | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV53158233; called by muse, mutect2, varscan2
- ZNF689 | c.1105G>A p.G369R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764153758, COSV54907925; called by muse, mutect2, varscan2
- ZNF813 | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs780761570, COSV67175944; called by muse, mutect2
- ZNF813 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs200579437, COSV67175947; called by muse, mutect2, varscan2
- ZNF99 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV68055039; called by muse, mutect2, varscan2
- ADCY3 | c.2967dup p.D990Rfs*26 | Frame Shift Ins (INS) | VAF 31/119 reads (26%) | called by mutect2, pindel, varscan2
- FOSL2 | c.352dup p.Q118Pfs*5 | Frame Shift Ins (INS) | VAF 24/91 reads (26%) | called by mutect2, pindel, varscan2
- H3C1 | c.384_407del p.R129_A136del | In Frame Del (DEL) | VAF 14/33 reads (42%) | called by mutect2, pindel
- PRAMEF15 | c.1034T>G p.I345S | Missense Mutation (SNP) | VAF 90/481 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TMEM161B | c.728dup p.L243Ffs*90 | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- ARSI | c.1158G>A p.T386= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as rs757161790, COSV100155961, COSV60816860; called by muse, mutect2, varscan2
- CIDEA | c.357G>A p.S119= | Silent (SNP) | VAF 34/69 reads (49%) | catalogued as rs140727009; called by muse, mutect2, varscan2
- CORO1A | c.309C>T p.D103= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV54630615; called by muse, mutect2, varscan2
- CYP1A2 | c.183G>A p.P61= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs998822071, COSV59659161; called by muse, mutect2, varscan2
- DPP6 | c.1422C>T p.N474= (on ENST00000377770 / NM_001364500.2; = p.N412= on NM_001936.5) | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs202156140; called by muse, mutect2, varscan2
- ERC2 | c.1482G>A p.A494= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs561414069, COSV55606697; called by muse, mutect2
- GLS2 | c.186T>C p.D62= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV61736920; called by muse, mutect2, varscan2
- HOXD10 | c.165G>A p.P55= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as rs1438215691, COSV50898406; called by muse, mutect2, varscan2
- KRT40 | c.1131C>T p.D377= | Silent (SNP) | VAF 41/539 reads (8%) | catalogued as rs778187410, COSV66696069; called by muse, mutect2
- OBP2A | c.39C>T p.A13= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs750955196; called by mutect2, varscan2
- PCDH10 | c.93C>T p.G31= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as COSV52089086; called by muse, mutect2, varscan2
- PRAMEF19 | c.78C>T p.S26= | Silent (SNP) | VAF 22/130 reads (17%) | catalogued as rs1190373058; called by muse, varscan2
- PXDN | c.2271C>A p.G757= | Silent (SNP) | VAF 55/162 reads (34%) | catalogued as COSV53228546; called by muse, mutect2, varscan2
- PYCARD | c.285C>T p.A95= | Silent (SNP) | VAF 11/83 reads (13%) | catalogued as COSV56008134; called by muse, mutect2, varscan2
- RXFP3 | c.111G>A p.T37= | Silent (SNP) | VAF 82/129 reads (64%) | catalogued as COSV100347146, COSV57504436; called by muse, mutect2, varscan2
- SHE | c.921G>A p.A307= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs373607892; called by muse, mutect2, varscan2
- SLC6A1 | c.453G>A p.L151= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as COSV55113737; called by muse, mutect2, varscan2
- SRGAP1 | c.975G>A p.A325= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as rs745401734, COSV61895193; called by muse, mutect2, varscan2
- TEFM | c.912C>G p.L304= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV58972572; called by muse, mutect2, varscan2
- TMPRSS9 | c.654C>T p.S218= (on ENST00000648592; = p.S184= on NM_182973.2) | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs371110843, COSV100211096; called by muse, mutect2, varscan2
- TNFRSF1A | c.576G>A p.T192= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs779458638, COSV50598605; called by muse, mutect2, varscan2
- ZBTB46 | c.30C>T p.I10= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs755709471, COSV55507487; called by muse, mutect2, varscan2
- ZFAT | c.1647G>A p.P549= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs776978202, COSV64735614; called by muse, mutect2
- ZNF418 | c.231T>A p.S77= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV68675661; called by muse, mutect2, varscan2
- ACP4 | chr19:50798115 del CCAGGATTCTGGCCTGCTTCACCCCTGGAGCACCAGG | 3'Flank (DEL) | VAF 20/161 reads (12%) | called by mutect2, pindel
- CTBP2 | c.58+12767G>T | Intron (SNP) | VAF 21/60 reads (35%) | catalogued as COSV100456529; called by muse, mutect2, varscan2
- GAS8 | c.90+1601G>A | Intron (SNP) | VAF 24/93 reads (26%) | catalogued as rs766188860, COSV51942443; called by muse, mutect2, varscan2
